Somatic mutation profile of tumor specimen TCGA-BR-4292-01A (aliquot TCGA-BR-4292-01A-01D-1126-08) from TCGA case TCGA-BR-4292, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; Tumor grade: G1; Age at diagnosis: 73.0 years (26,670 days).
Specimen TCGA-BR-4292-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e12498-6cf7-4520-bc33-ab706ea6809d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4292-11A (Solid Tissue Normal), aliquot TCGA-BR-4292-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcc7e515-acb7-45ad-a94b-cf4169a2a703

The open-access MAF lists 1,627 somatic variants for this specimen: 1,246 protein-altering or splice-affecting, 343 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 798, Silent 343, Frame Shift Del 290, Frame Shift Ins 73, Nonsense Mutation 44, Splice Site 18, RNA 15, In Frame Del 14, Splice Region 8, Intron 7, 3'UTR 6, 3'Flank 4.

Variants (750 of 1,627; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6473G>A p.R2158Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs142069738; called by muse, mutect2, varscan2
- CEP250 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as rs1341298773, COSV61170127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777685454, CM1212567, CM124359, COSV58368894, COSV58370113; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CSPP1 | c.2831del p.N944Mfs*2 (on ENST00000676605; = p.N903Mfs*2 on NM_024790.6) | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | catalogued as rs863225190, COSV51582895; ClinVar: pathogenic; called by mutect2, varscan2
- CUBN | c.1230+1G>A p.X410_splice | Splice Site (SNP) | VAF 41/131 reads (31%) | catalogued as rs386833766, CS040834, COSV64716345; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNAAF4 | c.583del p.I195* | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs753649614, CD138279; ClinVar: pathogenic; called by mutect2, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 30/157 reads (19%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- HDAC8 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs397515417, CM128299, COSV65265074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MDC1 | c.3073_3075del p.K1025del | In Frame Del (DEL) | VAF 27/88 reads (31%) | hotspot (GDC flag); catalogued as rs1472156046; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 22/241 reads (9%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PEX1 | c.1108del p.I370Lfs*17 | Frame Shift Del (DEL) | VAF 58/156 reads (37%) | catalogued as rs61750406; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PLA2G6 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587784327, CM090235, COSV59269917; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 68/248 reads (27%) | catalogued as rs368980595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SHANK2 | c.1896dup p.D633Rfs*3 | Frame Shift Ins (INS) | VAF 62/156 reads (40%) | catalogued as rs1555013332; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- A2M | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs745894309, COSV104404300, COSV59385156; called by muse, mutect2, varscan2
- AADACL2 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as rs200370690, COSV62929953; called by muse, mutect2, varscan2
- ABCA13 | c.10098G>T p.M3366I | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV71288358; called by muse, mutect2, varscan2
- ABCA13 | c.11013T>G p.F3671L | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.752); catalogued as COSV71288362; called by muse, mutect2, varscan2
- ABCB10 | c.1415A>C p.E472A | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV60621267; called by muse, mutect2, varscan2
- ABCC12 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs766670563, COSV60913530; called by muse, mutect2, varscan2
- ABCC9 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV53972766; called by muse, mutect2, varscan2
- ABCF1 | c.1948A>G p.M650V (on ENST00000326195 / NM_001025091.2; = p.M612V on NM_001090.3) | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1048441743, COSV58229200; called by muse, mutect2, varscan2
- ABCG8 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs764334802, COSV55393476; called by muse, mutect2, varscan2
- ABLIM3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs769545470, COSV58643673; called by muse, mutect2, varscan2
- ABT1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as COSV51291397; called by muse, mutect2, varscan2
- ACAT2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV58458936; called by muse, mutect2, varscan2
- ACCS | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55458340; called by muse, mutect2, varscan2
- ACE2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs759590772, COSV53025209, COSV53027016; called by muse, varscan2
- ACOT12 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774015295, COSV56895074; called by muse, mutect2, varscan2
- ACSL3 | c.1312C>T p.R438* | Nonsense Mutation (SNP) | VAF 36/54 reads (67%) | catalogued as COSV62482292; called by muse, mutect2, varscan2
- ACSM4 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs755148242, COSV68067243; called by muse, mutect2, varscan2
- ACSS1 | c.625A>G p.N209D | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as rs1283374079, COSV60220563; called by muse, mutect2, varscan2
- ACVR2A | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV54023081; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 88/127 reads (69%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs937654827, COSV65561170; called by muse, mutect2, varscan2
- ADAMDEC1 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV56475366; called by muse, mutect2
- ADAMTS17 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.881); catalogued as rs777227721, COSV51472377; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 58/106 reads (55%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS18 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs149189203; called by muse, mutect2, varscan2
- ADARB1 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV62344476; called by muse, mutect2, varscan2
- ADCY2 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs141886153, COSV100602683; called by muse, mutect2, varscan2
- ADCY5 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59198358; called by muse, mutect2, varscan2
- ADCY8 | c.3076C>T p.R1026* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as rs752100162, COSV53909048; called by muse, mutect2, varscan2
- ADGRA2 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV59443719; called by muse, mutect2, varscan2
- ADGRV1 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1159317263, COSV104434944, COSV67985791; called by muse, mutect2, varscan2
- ADNP | c.2356A>C p.I786L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.31); catalogued as COSV62425444; called by muse, mutect2, varscan2
- ADORA1 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV58810537; called by muse, mutect2, varscan2
- ADRA1B | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60701883; called by muse, mutect2, varscan2
- ADSS1 | c.741dup p.K248Qfs*16 | Frame Shift Ins (INS) | VAF 10/30 reads (33%) | catalogued as rs769542442; called by mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 17/125 reads (14%) | catalogued as rs748399150; called by mutect2, varscan2
- AGTPBP1 | c.1358G>A p.R453H (on ENST00000357081 / NM_001330701.2; = p.R413H on NM_015239.2) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as rs1457551466, COSV61271241; called by muse, mutect2, varscan2
- AKAP13 | c.4249T>C p.F1417L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV63457892; called by muse, mutect2, varscan2
- AKAP17A | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs771306611, COSV58309714; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as COSV62339755; called by mutect2, varscan2
- AKT2 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs991833403, COSV60908515, COSV60909160; called by muse, mutect2, varscan2
- ALDH18A1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1305993720, COSV64662642; called by muse, mutect2, varscan2
- ALDH5A1 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.948); catalogued as COSV62373625, COSV62374251; called by muse, mutect2, varscan2
- ALG13 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52639312; called by muse, mutect2, varscan2
- ALOX12B | c.1654+2T>C p.X552_splice | Splice Site (SNP) | VAF 42/132 reads (32%) | catalogued as COSV59873045; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 59/238 reads (25%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ALPK3 | c.4739T>A p.M1580K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51933749; called by muse, mutect2, varscan2
- ALS2 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51887375; called by muse, mutect2, varscan2
- AMBRA1 | c.3670C>T p.R1224* (on ENST00000458649 / NM_001367468.1; = p.R1134* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs1023861260, COSV54053486; called by muse, mutect2, varscan2
- AMBRA1 | c.1310C>T p.P437L (on ENST00000458649 / NM_001367468.1; = p.P347L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs373429644; called by muse, mutect2, varscan2
- AMBRA1 | c.227A>C p.N76T | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.971); catalogued as COSV54054382; called by muse, mutect2, varscan2
- AMIGO3 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs752196987, COSV57538659; called by muse, mutect2, varscan2
- AMPD3 | c.299dup p.A101Gfs*29 (on ENST00000396553 / NM_001025389.2; = p.A110Gfs*29 on NM_000480.3) | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | catalogued as rs751130603; called by mutect2, varscan2
- ANAPC2 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs375485364, COSV59244588; called by muse, mutect2
- ANGPTL2 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV52222425; called by muse, mutect2, varscan2
- ANKH | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs748715503, COSV52478882; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 36/71 reads (51%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD26 | c.4976del p.N1659Ifs*2 | Frame Shift Del (DEL) | VAF 41/151 reads (27%) | catalogued as rs762275496; called by mutect2, pindel, varscan2
- ANKRD6 | c.2020G>A p.A674T (on ENST00000339746 / NM_001242809.2; = p.A669T on NM_014942.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1563187843, COSV60231710; called by muse, mutect2, varscan2
- ANKS6 | c.1730C>T p.T577M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs770988126, COSV62050350; called by muse, mutect2, varscan2
- ANO9 | c.2254C>T p.Q752* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV60383613; called by muse, mutect2, varscan2
- ANTXR1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774300710, COSV58013918; called by muse, mutect2, varscan2
- ANXA13 | c.391+1G>A p.X131_splice | Splice Site (SNP) | VAF 56/322 reads (17%) | catalogued as rs780416939, COSV51623529; called by muse, mutect2, varscan2
- AOC3 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs764239863, COSV53826743; called by muse, mutect2, varscan2
- AP1AR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1040972332, COSV56769126; called by muse, mutect2, varscan2
- AP2M1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); catalogued as COSV53048043; called by muse, mutect2, varscan2
- AP5B1 | c.572T>C p.L191P | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57503019; called by muse, mutect2, varscan2
- APAF1 | c.1805dup p.N602Kfs*24 (on ENST00000551964 / NM_181861.2; = p.N591Kfs*24 on NM_001160.3) | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | catalogued as rs758129366; called by mutect2, varscan2
- APBB1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs139345068; called by muse, mutect2, varscan2
- APEX1 | c.871_872del p.L291Vfs*6 | Frame Shift Del (DEL) | VAF 58/228 reads (25%) | catalogued as rs747329195; called by pindel, varscan2
- API5 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs1177935849, COSV101124623, COSV66632411, COSV66633371; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 40/138 reads (29%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARFGAP3 | c.687del p.G230Efs*26 | Frame Shift Del (DEL) | VAF 43/119 reads (36%) | catalogued as rs754931118; called by mutect2, varscan2
- ARFGEF2 | c.2561T>G p.L854R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV64212453; called by muse, mutect2, varscan2
- ARFGEF2 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs748682883, COSV64212456; called by muse, mutect2, varscan2
- ARHGAP18 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV63764520; called by muse, varscan2
- ARHGAP26 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs760497830, COSV50829906; called by muse, mutect2, varscan2
- ARHGAP26 | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | catalogued as rs1484850928, COSV50829924; called by muse, mutect2, varscan2
- ARHGAP32 | c.4192C>T p.R1398C (on ENST00000310343 / NM_001378025.1; = p.R1049C on NM_014715.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); catalogued as rs112097648, COSV59848334; called by muse, mutect2, varscan2
- ARHGAP36 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); catalogued as COSV52267090, COSV99358205; called by muse, mutect2, varscan2
- ARHGEF16 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1446846571, COSV65681461; called by muse, mutect2, varscan2
- ARHGEF19 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776756182, COSV54616729; called by muse, mutect2, varscan2
- ARHGEF6 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as rs376242035, COSV51691159, COSV51696761; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.4390C>T p.R1464C | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.993); catalogued as rs760589011, COSV57602539; called by muse, mutect2, varscan2
- ARIH2 | c.538+2T>C p.X180_splice | Splice Site (SNP) | VAF 23/62 reads (37%) | catalogued as COSV62704861; called by muse, mutect2, varscan2
- ARMT1 | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV66178491, COSV66178587; called by mutect2, varscan2
- ARSD | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1569085008, COSV66973324; called by muse, mutect2, varscan2
- ASTN2 | c.550G>C p.A184P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.132); catalogued as COSV57779784; called by muse, mutect2, varscan2
- ASXL3 | c.3817A>G p.T1273A | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1366857924, COSV52466913; called by muse, mutect2, varscan2
- ATAD2 | c.4024A>T p.K1342* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as rs761794223, COSV54878294, COSV54881114; called by muse, mutect2, varscan2
- ATG14 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.091); catalogued as rs144919020; called by muse, mutect2, varscan2
- ATM | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587779858, COSV53740048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP12A | c.134dup p.N45Kfs*14 | Frame Shift Ins (INS) | VAF 22/111 reads (20%) | catalogued as rs1211915800; called by mutect2, pindel, varscan2
- ATP1B1 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV63167064; called by muse, mutect2
- ATP2B3 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 40/135 reads (30%) | catalogued as COSV54848138; called by muse, mutect2, varscan2
- ATP8A2 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs781078252, COSV54953190; called by muse, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1268253442; called by mutect2, pindel
- ATRN | c.3055G>T p.G1019C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV53528029; called by muse, mutect2, varscan2
- ATXN2L | c.2594C>G p.A865G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); catalogued as COSV57370807; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- B3GALT2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as rs766787048, COSV66464061; called by muse, mutect2, varscan2
- B4GALNT4 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232868117, COSV57323444; called by muse, mutect2, varscan2
- BACH2 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV57593236; called by muse, mutect2, varscan2
- BAG4 | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV54860254; called by muse, mutect2, varscan2
- BATF | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV54376459; called by muse, varscan2
- BAZ2A | c.4130C>T p.T1377M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs772724992, COSV51637103; called by muse, mutect2, varscan2
- BICRAL | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as COSV58405765; called by muse, mutect2, varscan2
- BMP3 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV51085142; called by muse, mutect2, varscan2
- BMP6 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs144134653; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BORA | c.1201C>T p.P401S (on ENST00000613797; = p.P326S on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.534); catalogued as COSV64695287; called by muse, mutect2, varscan2
- BRF2 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs983775121, COSV55103603; called by muse, mutect2, varscan2
- BRINP3 | c.1866del p.F622Lfs*8 | Frame Shift Del (DEL) | VAF 115/401 reads (29%) | catalogued as COSV66513610; called by mutect2, pindel, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BRWD3 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as rs759433345, COSV64748502; called by muse, mutect2, varscan2
- C1QTNF7 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1226996127, COSV54851075, COSV54852756; called by muse, mutect2, varscan2
- C1orf21 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs200095614, COSV52405964; called by muse, varscan2
- C2CD3 | c.4901C>T p.T1634M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs559034596, COSV58093359; called by muse, mutect2, varscan2
- C2CD3 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as rs1406007301, CD164515; called by mutect2, pindel
- C3orf20 | c.2367dup p.K790Efs*39 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs762124133; called by mutect2, pindel, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 8/17 reads (47%) | catalogued as rs750735753; called by mutect2, varscan2
- C8orf34 | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs1263051720, COSV61380757; called by muse, mutect2, varscan2
- CA6 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555895182, COSV66262083; called by muse, mutect2, varscan2
- CACNA1G | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61728158; called by muse, mutect2
- CACNA1I | c.5080G>A p.D1694N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.83); catalogued as rs772474527, COSV100358984; called by muse, varscan2
- CACNG4 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1466892036, COSV50924354, COSV50925321; called by muse, mutect2, varscan2
- CACTIN | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV50268326; called by muse, mutect2, varscan2
- CADM1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1216125604, COSV59010956; called by muse, mutect2, varscan2
- CADM4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV55928371; called by muse, mutect2, varscan2
- CADPS | c.2876G>A p.R959H | Missense Mutation (SNP) | VAF 90/272 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); catalogued as rs376315928; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMKK1 | c.587T>C p.V196A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV50117228; called by muse, mutect2, varscan2
- CAMKV | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.255); catalogued as rs756893325, COSV56555563; called by muse, mutect2, varscan2
- CARD10 | c.1823del p.P608Qfs*75 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs1266428698; called by mutect2, pindel, varscan2
- CARMIL3 | c.899T>C p.F300S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV57726525; called by muse, mutect2, varscan2
- CARNMT1 | c.1219A>G p.K407E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV65193640; called by muse, mutect2, varscan2
- CASP6 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54460164; called by muse, mutect2
- CBLN1 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV54654078; called by muse, mutect2, varscan2
- CCDC17 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs1048761273, COSV51969501, COSV99322283; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC28A | c.80del p.N27Mfs*5 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as rs756347761; called by mutect2, varscan2
- CCDC40 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs61736668, COSV53896744; called by muse, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs749079180; called by mutect2, varscan2
- CCDC81 | c.1886G>A p.R629H (on ENST00000445632 / NM_001156474.2; = p.R539H on NM_021827.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs780072627, COSV53578606; called by muse, mutect2, varscan2
- CCDC82 | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as rs1181649103, COSV53593585; called by muse, mutect2, varscan2
- CCDC97 | c.970_972del p.E324del | In Frame Del (DEL) | VAF 35/100 reads (35%) | catalogued as rs894590475; called by pindel, varscan2
- CCIN | c.1532G>A p.C511Y | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.974); catalogued as COSV58724242; called by muse, mutect2, varscan2
- CCT3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55289205; called by muse, mutect2, varscan2
- CCT8L2 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs774406718, COSV63461984, COSV63463524; called by muse, mutect2, varscan2
- CCT8L2 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.216); catalogued as COSV63462538, COSV63463235; called by muse, mutect2, varscan2
- CDAN1 | c.2591G>T p.R864L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV62332117; called by muse, mutect2, varscan2
- CDH10 | c.1655dup p.N552Kfs*5 | Frame Shift Ins (INS) | VAF 7/31 reads (23%) | catalogued as rs754722288; called by mutect2, pindel, varscan2
- CDH19 | c.1841del p.L614* | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | catalogued as rs1568168060; called by mutect2, pindel, varscan2
- CDH20 | c.2134G>A p.V712M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.945); catalogued as COSV53010214; called by muse, mutect2
- CDH22 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs746195921, COSV64837681; called by muse, mutect2, varscan2
- CDH23 | c.3865G>A p.A1289T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56465669; called by muse, mutect2, varscan2
- CDH23 | c.9430G>A p.A3144T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs779358121, COSV56465682; called by muse, mutect2, varscan2
- CDH5 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as rs563015942, COSV58517643; called by muse, mutect2
- CDHR1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760927412, COSV60562604; called by muse, mutect2, varscan2
- CDHR1 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs202085286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDK5RAP1 | c.932T>C p.V311A (on ENST00000357886 / NM_001365728.1; = p.V297A on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59426963; called by muse, mutect2, varscan2
- CDKL5 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66111451; called by muse, mutect2
- CENPI | c.1325G>A p.S442N | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.919); catalogued as COSV54502967; called by muse, varscan2
- CEP104 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as rs1260661463, COSV65512338; called by muse, mutect2, varscan2
- CEP170B | c.457C>T p.R153W (on ENST00000453495; = p.R83W on NM_015005.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765432805, COSV69024664; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP44 | c.838_840del p.L280del | In Frame Del (DEL) | VAF 28/95 reads (29%) | catalogued as rs779217465; called by pindel, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 7/32 reads (22%) | catalogued as rs768479535; called by mutect2, pindel
- CFAP52 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100235372, COSV55345128; called by muse, mutect2, varscan2
- CFAP65 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780369416, COSV100444804, COSV58561337; called by muse, mutect2, varscan2
- CGNL1 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs200755121; called by muse, mutect2, varscan2
- CHD3 | c.4907G>T p.G1636V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV57875364; called by muse, mutect2, varscan2
- CHRNA9 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as rs761475834, COSV59574590; called by muse, mutect2, varscan2
- CHST1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1333206256, COSV57322764; called by muse, mutect2, varscan2
- CHST5 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60339346; called by muse, varscan2
- CKMT1B | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs750654362, COSV55852530; called by muse, mutect2, varscan2
- CLEC4F | c.1317G>T p.Q439H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV55479493; called by muse, mutect2, varscan2
- CLIP3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs765490934, COSV53324683; called by muse, mutect2, varscan2
- CMYA5 | c.5468del p.K1823Rfs*17 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as rs954878355; called by mutect2, pindel, varscan2
- CNN2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs200699249; called by muse, mutect2, varscan2
- CNNM1 | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63201736; called by muse, mutect2, varscan2
- CNNM2 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63995937; called by muse, mutect2, varscan2
- CNOT6 | c.750del p.L251Wfs*2 | Frame Shift Del (DEL) | VAF 28/109 reads (26%) | catalogued as COSV56160927; called by mutect2, pindel, varscan2
- CNTNAP2 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.352); catalogued as rs529269450, COSV62184996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs374805044; called by mutect2, varscan2
- COL12A1 | c.9153C>A p.S3051R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV59396532; called by muse, mutect2, varscan2
- COL17A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs568269377, COSV62226880; called by muse, mutect2, varscan2
- COL22A1 | c.1458G>T p.M486I | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV57337922; called by muse, mutect2, varscan2
- COL22A1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1241576170, COSV57331225, COSV57359419; called by muse, mutect2, varscan2
- COL5A1 | c.2433T>C p.G811= | Splice Region (SNP) | VAF 13/240 reads (5%) | catalogued as rs1554798918, COSV65669250; ClinVar: likely benign; called by muse, mutect2
- COL6A3 | c.7162+1G>A p.X2388_splice | Splice Site (SNP) | VAF 28/39 reads (72%) | catalogued as rs755754433, CS141594, COSV55090458; called by muse, mutect2, varscan2
- COL6A3 | c.4367G>A p.R1456Q | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV55087291; called by muse, mutect2, varscan2
- COL9A1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs745566207, COSV61832744; called by muse, mutect2, varscan2
- CORO7 | c.2149C>A p.L717M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV52030292; called by muse, mutect2, varscan2
- CPSF1 | c.2816G>T p.G939V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58233658; called by muse, mutect2
- CRACD | c.2185T>C p.S729P | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51721595; called by muse, mutect2, varscan2
- CREB1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV62064915; called by muse, mutect2, varscan2
- CRMP1 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV61480378; called by muse, mutect2, varscan2
- CRYBB1 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53233369; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYGA | c.476dup p.A160Cfs*29 | Frame Shift Ins (INS) | VAF 70/114 reads (61%) | catalogued as rs762650691; called by mutect2, varscan2
- CSMD3 | c.9074G>A p.R3025H (on ENST00000297405 / NM_001363185.1; = p.R2856H on NM_052900.3) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs199604170, COSV52182215; called by muse, mutect2, varscan2
- CSMD3 | c.8428A>T p.T2810S (on ENST00000297405 / NM_001363185.1; = p.T2641S on NM_052900.3) | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV52187794; called by muse, mutect2, varscan2
- CSN3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs770368585, COSV59243648, COSV59244130; called by muse, mutect2, varscan2
- CSPP1 | c.475C>T p.R159W (on ENST00000676605; = p.R118W on NM_024790.6) | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1024300760, COSV51582107; called by muse, mutect2, varscan2
- CUBN | c.9557T>C p.V3186A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV64716340; called by muse, mutect2, varscan2
- CUL9 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1384090763, COSV52725944; called by muse, mutect2, varscan2
- DCAF4L2 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV60476700; called by muse, mutect2, varscan2
- DDX11 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs758908151, COSV52504550; called by muse, mutect2, varscan2
- DDX60 | c.2784C>T p.T928= | Splice Region (SNP) | VAF 25/74 reads (34%) | catalogued as rs145361158; called by muse, mutect2, varscan2
- DENND1A | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.358); catalogued as rs1465850668, COSV101011734, COSV101011954; called by muse, mutect2, varscan2
- DENND1B | c.1775A>T p.D592V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV54149261; called by muse, mutect2, varscan2
- DENND3 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as rs1463130072, COSV52802588; called by muse, mutect2, varscan2
- DENND5A | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs369856493; called by muse, mutect2, varscan2
- DFFB | c.779A>G p.H260R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58860808; called by muse, mutect2, varscan2
- DGCR2 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.287); catalogued as rs777495657, COSV54218622; called by muse, mutect2, varscan2
- DGKH | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs775620105, COSV54932410; called by muse, mutect2, varscan2
- DGKI | c.2059G>T p.A687S | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as COSV55951430; called by muse, mutect2, varscan2
- DHX35 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs778423906, COSV52670403; called by muse, mutect2
- DHX36 | c.1831T>A p.C611S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57672832; called by muse, mutect2, varscan2
- DLGAP1 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs1160652768, COSV59799384; called by muse, mutect2, varscan2
- DLX6 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50293892; called by muse, mutect2, varscan2
- DNAH11 | c.6565C>T p.R2189* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs778698443, COSV60954805; called by muse, varscan2
- DNAH9 | c.8647A>G p.T2883A | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV52350917; called by muse, mutect2, varscan2
- DNASE1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774890803, COSV55913317; called by muse, mutect2, varscan2
- DOCK1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs745478937, COSV54740791; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.5218A>G p.N1740D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.073); catalogued as COSV70237191; called by muse, mutect2
- DPAGT1 | c.698dup p.T234Hfs*116 | Frame Shift Ins (INS) | VAF 46/182 reads (25%) | catalogued as rs35482889; called by mutect2, varscan2
- DPPA4 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV59510512; called by muse, mutect2
- DPYSL3 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs757343684, COSV58326939; called by muse, mutect2, varscan2
- DRC7 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs1279424490, COSV61054841; called by muse, mutect2, varscan2
- DRD5 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs749131704, COSV58576592, COSV58578112; called by muse, mutect2, varscan2
- DSCAML1 | c.3362A>G p.Q1121R (on ENST00000321322; = p.Q1061R on NM_020693.4) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV58391136; called by muse, mutect2, varscan2
- DSCC1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143137070; called by muse, mutect2, varscan2
- DUSP16 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs201815856, COSV53807759; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 32/108 reads (30%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- E2F7 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754738203, COSV59738194; called by muse, mutect2, varscan2
- EAPP | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.478); catalogued as COSV51651862; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 36/65 reads (55%) | catalogued as rs369293935; called by mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 31/81 reads (38%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EGFL8 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs149576421, COSV61248796; called by muse, mutect2, varscan2
- EHMT1 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58375316; called by muse, mutect2, varscan2
- EIF3B | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV62803490; called by muse, mutect2, varscan2
- EIF5B | c.3314G>A p.R1105Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51485425; called by muse, mutect2, varscan2
- ELAPOR2 | c.2719T>C p.C907R (on ENST00000450689 / NM_001142749.3; = p.C740R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51887159; called by muse, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs770453803; called by mutect2, varscan2
- ENPP2 | c.1801C>T p.R601* (on ENST00000075322 / NM_001040092.3; = p.R653* on NM_006209.5) | Nonsense Mutation (SNP) | VAF 16/113 reads (14%) | catalogued as rs764313249, COSV50015385; called by muse, mutect2, varscan2
- ENTPD8 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV58162030; called by muse, mutect2, varscan2
- EP300 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs1303184977, COSV54333110; called by muse, mutect2, varscan2
- EPB41L4B | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781369450, COSV65797013; called by muse, mutect2, varscan2
- EPG5 | c.6482A>G p.Y2161C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56350230; called by muse, mutect2, varscan2
- EPHA7 | c.2170A>G p.R724G | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65183182; called by muse, mutect2, varscan2
- EPHB2 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.96); catalogued as COSV65862713; called by muse, mutect2, varscan2
- EPHX2 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs771290052, COSV100994456; called by mutect2, varscan2
- EPS8L2 | c.1412del p.P471Rfs*49 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as COSV59350488; called by mutect2, pindel, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 20/96 reads (21%) | catalogued as rs768793415; called by mutect2, varscan2
- ERF | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV55896081; called by muse, mutect2, varscan2
- ERICH3 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs371417037, COSV100446075, COSV58602494; called by muse, mutect2, varscan2
- ESRRB | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs376901347; called by muse, mutect2, varscan2
- EVPL | c.3935C>T p.T1312M | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs145535523; called by muse, varscan2
- EVPL | c.3788G>A p.S1263N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs746724427, COSV56911362; called by muse, varscan2
- EXO1 | c.2190del p.D731Tfs*4 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | catalogued as rs752940417; called by mutect2, pindel, varscan2
- EXOC2 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 44/126 reads (35%) | catalogued as COSV57863822; called by muse, varscan2
- EXPH5 | c.1166T>G p.L389R | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV56202692; called by muse, mutect2, varscan2
- EXTL1 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1207352873, COSV65337607; called by muse, mutect2, varscan2
- EXTL3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.09); catalogued as COSV55038153; called by muse, mutect2, varscan2
- EYS | c.1616G>T p.C539F | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV60986255; called by muse, mutect2, varscan2
- F13B | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs778659939, COSV100803351, COSV66372407; called by muse, mutect2, varscan2
- F8 | c.3870del p.E1292Rfs*16 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as rs1426645898, CD022147, CD0911173, COSV64270790; called by mutect2, pindel, varscan2
- FAH | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as rs11555097, COSV55721560; called by muse, mutect2, varscan2
- FAM111A | c.965del p.N322Mfs*16 | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | catalogued as rs771628793; called by mutect2, pindel, varscan2
- FAM120C | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs868985593, COSV100069505; called by muse, varscan2
- FAM13B | c.2509C>T p.R837* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as COSV50366634; called by muse, mutect2, varscan2
- FAM13B | c.1603C>T p.H535Y | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV50366671; called by muse, mutect2, varscan2
- FAM13C | c.701A>C p.N234T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV53248872; called by muse, mutect2, varscan2
- FAM160A2 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1330613310, COSV56411594; called by muse, mutect2, varscan2
- FAM161B | c.265G>A p.A89T (on ENST00000651776; = p.A26T on NM_152445.3) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs747198305, COSV53178791; called by muse, mutect2, varscan2
- FAM167A | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | catalogued as COSV52703634; called by muse, mutect2, varscan2
- FAM199X | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs782702516, COSV55433214, COSV55433623; called by muse, mutect2, varscan2
- FAM221B | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); catalogued as rs943024291, COSV65074389; called by muse, mutect2, varscan2
- FAM222A | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62723358; called by muse, mutect2, varscan2
- FAM47A | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); catalogued as rs762990565, COSV60496973; called by muse, mutect2, varscan2
- FAM50A | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50131329; called by muse, mutect2, varscan2
- FAM78A | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs754847204, COSV55991853, COSV55992808; called by muse, mutect2, varscan2
- FAP | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as rs769751511, COSV51862099, COSV51867397; called by muse, mutect2, varscan2
- FARP1 | c.2472C>A p.C824* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV60337908; called by muse, mutect2
- FAT2 | c.257A>C p.E86A | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV55820208; called by muse, mutect2, varscan2
- FAT3 | c.3160G>C p.E1054Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53115002, COSV53159803; called by muse, mutect2, varscan2
- FAT4 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1274655349, COSV67887321; called by muse, mutect2, varscan2
- FBLL1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs532800847, COSV100606117; called by muse, varscan2
- FBLN1 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); catalogued as rs775498492, COSV59937631; called by muse, mutect2, varscan2
- FBXO8 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67031565; called by muse, mutect2, varscan2
- FCHO2 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs1205811954, COSV59272470; called by muse, mutect2, varscan2
- FCN1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs541616038, COSV65662384; called by muse, mutect2, varscan2
- FER1L6 | c.5390A>T p.N1797I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67550094; called by muse, mutect2, varscan2
- FGF13 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59545905; called by muse, mutect2, varscan2
- FGFR2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60647650; called by muse, mutect2, varscan2
- FHOD1 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs770549814, COSV50761048; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | catalogued as COSV58769165; called by mutect2, varscan2
- FLG | c.11720G>A p.R3907H | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs554551056, COSV64242250; called by muse, mutect2, varscan2
- FLNC | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1357772572, COSV57956277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FN3K | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs567326977, COSV56182063; called by muse, mutect2, varscan2
- FOLR2 | c.232T>G p.F78V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53351623; called by muse, varscan2
- FOXA3 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56216154; called by muse, mutect2, varscan2
- FOXF1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286663; called by muse, mutect2, varscan2
- FOXP2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63486491; called by muse, mutect2, varscan2
- FRAS1 | c.6284C>T p.A2095V | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.787); catalogued as rs1205557714, COSV53612651; called by muse, mutect2, varscan2
- FREM2 | c.6346G>A p.A2116T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.206); catalogued as COSV54838777; called by muse, mutect2, varscan2
- FRMPD1 | c.3661G>A p.V1221I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs200892375; called by muse, mutect2, varscan2
- FRMPD3 | c.3794C>T p.T1265I | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV99345482; called by muse, mutect2, varscan2
- FRMPD4 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs367552176, COSV66215244; called by muse, mutect2, varscan2
- FRYL | c.3146C>T p.A1049V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as rs766346765, COSV51947826; called by muse, mutect2, varscan2
- FSCB | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs371199022; called by muse, mutect2, varscan2
- FSHR | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as rs369191560, COSV58624116; called by muse, mutect2, varscan2
- FUBP1 | c.1609T>C p.W537R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV53931497; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs756304971; called by mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GABRP | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1336167569, COSV54662954; called by muse, mutect2, varscan2
- GAL3ST3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.944); catalogued as rs1290136225, COSV61749009; called by muse, mutect2, varscan2
- GALNT11 | c.1812G>A p.W604* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV57426105; called by muse, mutect2, varscan2
- GART | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); catalogued as COSV63113831; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GCN1 | c.4702G>A p.V1568I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765063929, COSV56104268; called by muse, mutect2, varscan2
- GDPD1 | c.903T>A p.Y301* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV52381825; called by muse, mutect2, varscan2
- GDPD5 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as rs750559361, COSV61127747; called by muse, mutect2, varscan2
- GGA3 | c.413T>C p.L138P (on ENST00000537686 / NM_138619.4; = p.L105P on NM_014001.5) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55456859; called by muse, mutect2, varscan2
- GJA1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as rs2228961; called by muse, mutect2, varscan2
- GJA4 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV60725331; called by muse, mutect2, varscan2
- GLI3 | c.3497G>T p.S1166I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67888821; called by muse, mutect2, varscan2
- GLI3 | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV67888826; called by muse, mutect2, varscan2
- GLIS1 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56549154; called by muse, mutect2, varscan2
- GLIS2 | c.422C>G p.A141G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV52110698; called by muse, mutect2, varscan2
- GLYATL1 | c.860G>A p.C287Y (on ENST00000317391 / NM_001354699.1; = p.C318Y on NM_080661.4) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55609009; called by muse, mutect2, varscan2
- GNPTG | c.638T>G p.F213C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50190087; called by muse, mutect2, varscan2
- GOLGA1 | c.573del p.E192Kfs*4 | Frame Shift Del (DEL) | VAF 29/156 reads (19%) | catalogued as rs1564340624; called by mutect2, pindel, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLT1A | c.221del p.G74Vfs*64 | Frame Shift Del (DEL) | VAF 51/175 reads (29%) | catalogued as rs765260894; called by mutect2, pindel, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 33/180 reads (18%) | catalogued as rs370114090; called by mutect2, varscan2
- GPATCH2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1344694660, COSV65127770; called by muse, mutect2
- GPI | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs773208058, COSV55825438; called by muse, mutect2, varscan2
- GPIHBP1 | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV58209304; called by muse, mutect2, varscan2
- GPR158 | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs146528842; called by muse, mutect2, varscan2
- GPR158 | c.3366dup p.K1123Qfs*10 | Frame Shift Ins (INS) | VAF 27/82 reads (33%) | catalogued as rs771672605; called by mutect2, varscan2
- GPR173 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868990662, COSV60234969; called by muse, mutect2, varscan2
- GPR180 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs773974365, COSV65385411; called by muse, mutect2, varscan2
- GPR32 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV54514647, COSV54514904; called by muse, mutect2, varscan2
- GPR37 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100390472; called by muse, varscan2
- GPR89B | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as rs782562694; called by mutect2, varscan2
- GRAMD1A | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1164519549, COSV58767171; called by muse, mutect2, varscan2
- GRAMD4 | c.1061A>T p.Y354F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63030363; called by muse, mutect2, varscan2
- GRIP1 | c.2675C>T p.S892F (on ENST00000359742 / NM_001379345.1; = p.S840F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV54024986; called by muse, mutect2, varscan2
- GRK2 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57951825; called by muse, mutect2, varscan2
- GRM5 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59606017; called by muse, mutect2, varscan2
- GSK3B | c.609-1G>C p.X203_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as COSV51776024; called by muse, mutect2, varscan2
- GSX2 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58842920; called by muse, mutect2, varscan2
- GTDC1 | c.1155T>G p.C385W (on ENST00000344850 / NM_001354361.1; = p.C300W on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53995223; called by muse, mutect2, varscan2
- GTF3C1 | c.5587C>T p.R1863C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs1386514409, COSV62241431; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 17/75 reads (23%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- HCN2 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52114644; called by muse, mutect2, varscan2
- HCN3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs374622488, COSV64234087; called by muse, mutect2, varscan2
- HFM1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs766605643, COSV54027835; called by muse, mutect2, varscan2
- HGFAC | c.1800del p.L602Wfs*70 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs770643102; called by mutect2, pindel, varscan2
- HIP1R | c.2408A>G p.D803G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV53441737; called by muse, mutect2, varscan2
- HIRA | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as rs750582371, COSV54275155; called by muse, mutect2, varscan2
- HK1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53858648; called by muse, mutect2, varscan2
- HK1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV53858689; called by muse, mutect2, varscan2
- HLA-DRA | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV66622752; called by muse, mutect2, varscan2
- HMX3 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63501702; called by muse, mutect2, varscan2
- HNRNPH2 | c.814T>G p.S272A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.829); catalogued as COSV54509190; called by muse, mutect2, varscan2
- HNRNPM | c.895+1G>A p.X299_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57692731; called by muse, mutect2, varscan2
- HOGA1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs374047066; called by muse, mutect2, varscan2
- HOMER1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV56526404; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXB13 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1437427005, COSV51706087; called by muse, mutect2, varscan2
- HOXC12 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs373624523, COSV54535007; called by muse, mutect2, varscan2
- HOXC13 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498268; called by muse, mutect2, varscan2
- HOXD4 | c.481T>C p.Y161H | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60459917; called by muse, mutect2, varscan2
- HPS4 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs150403254, COSV61103584; called by muse, mutect2, varscan2
- HR | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as rs776309442, COSV57192283; called by muse, mutect2, varscan2
- HRG | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs149578094; called by muse, mutect2, varscan2
- HSD17B1 | c.617A>C p.D206A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56797780; called by muse, mutect2, varscan2
- HSPG2 | c.5860G>A p.G1954S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs561814891, COSV65971928; called by muse, mutect2, varscan2
- HSPH1 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.369); catalogued as COSV60711501; called by muse, mutect2, varscan2
- HTR1A | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as rs557845021, COSV60500946; called by muse, mutect2, varscan2
- HTR2C | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52211522, COSV99035027; called by muse, mutect2, varscan2
- HTR3B | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52744800; called by muse, mutect2, varscan2
- HTRA4 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV56759473; called by muse, mutect2, varscan2
- HYOU1 | c.1670A>C p.E557A | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68215854; called by muse, mutect2
- IDI1 | c.711dup p.E238Rfs*10 | Frame Shift Ins (INS) | VAF 15/85 reads (18%) | catalogued as rs1564482836; called by mutect2, pindel, varscan2
- IFT140 | c.2875C>T p.R959W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs537085826, COSV54152825; called by muse, mutect2, varscan2
- IGSF6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs780421744, COSV51679319; called by muse, mutect2, varscan2
- IKBKB | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs781098452, COSV60596626; called by muse, mutect2, varscan2
- IKZF2 | c.1289G>T p.R430M | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV100563944, COSV59578815; called by muse, mutect2, varscan2
- INHBB | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs546435911, COSV54677994; called by muse, mutect2, varscan2
- INO80 | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as COSV62738401; called by muse, mutect2, varscan2
- INPP5F | c.937T>G p.L313V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.621); catalogued as COSV62821464; called by muse, mutect2, varscan2
- INSIG2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99830381; called by muse, mutect2, varscan2
- INSYN2A | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749004305, COSV54738046; called by muse, varscan2
- INSYN2A | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs150536495, COSV54729162; called by muse, varscan2
- INVS | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 88/365 reads (24%) | catalogued as COSV52442347; called by muse, mutect2, varscan2
- IQSEC3 | c.3094C>T p.P1032S (on ENST00000538872 / NM_001170738.2; = p.P729S on NM_015232.1) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV58285124; called by muse, mutect2, varscan2
- IREB2 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.237); catalogued as rs746547492, COSV51921941, COSV99359826; called by mutect2, varscan2
- IRF2 | c.363A>G p.K121= | Splice Region (SNP) | VAF 49/70 reads (70%) | catalogued as COSV66929511; called by muse, mutect2, varscan2
- IRGC | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as COSV54984303; called by muse, mutect2, varscan2
- IRS4 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64533926; called by muse, mutect2, varscan2
- IRX3 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV61668255; called by muse, mutect2, varscan2
- IRX4 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs1218508334, COSV51472754; called by muse, mutect2, varscan2
- ISM2 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs961879912, COSV53633860, COSV53637437; called by muse, mutect2, varscan2
- ITGA11 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59877936; called by muse, mutect2, varscan2
- ITGAL | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs750373265, COSV63322312; called by muse, mutect2, varscan2
- ITGAX | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51646028; called by muse, mutect2, varscan2
- ITIH5 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs560482680, COSV53662315; called by mutect2, varscan2
- ITPR2 | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781094405, COSV67269718; called by muse, mutect2, varscan2
- JAG1 | c.2671G>A p.A891T | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1454234098, COSV54753385; ClinVar: uncertain significance; called by muse, varscan2
- KARS1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs574836321, COSV56692316; called by muse, mutect2, varscan2
- KAT2B | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.354); catalogued as rs1356312243, COSV55429637; called by muse, mutect2, varscan2
- KAZN | c.1725G>T p.Q575H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV65719295; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNJ12 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs148229779; called by muse, mutect2
- KCNK3 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs549923058, COSV57192632; called by muse, mutect2, varscan2
- KCNQ5 | c.1836+2T>C p.X612_splice | Splice Site (SNP) | VAF 9/108 reads (8%) | catalogued as COSV59660882; called by muse, mutect2
- KCNS3 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1200217697, COSV58406936; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KDM2B | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV65640980; called by muse, mutect2, varscan2
- KIAA0100 | c.4276C>T p.H1426Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV66493040; called by muse, mutect2, varscan2
- KIAA1549 | c.4625G>A p.R1542H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769427032, COSV54314850; called by muse, mutect2, varscan2
- KIAA1586 | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs773471612, COSV66056681, COSV66057402; called by muse, mutect2, varscan2
- KIF21B | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1200416395, COSV59758331; called by muse, mutect2, varscan2
- KIF27 | c.3936del p.S1313Vfs*5 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | catalogued as rs775622981; called by mutect2, pindel, varscan2
- KIF3C | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373846303; called by muse, mutect2, varscan2
- KIF9 | c.316del p.A106Qfs*21 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | catalogued as rs1374368753; called by mutect2, pindel, varscan2
- KLC4 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs781291050, COSV99431232; called by muse, mutect2, varscan2
- KLF4 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101012680, COSV65928966; called by muse, mutect2, varscan2
- KLHL2 | c.1613T>G p.V538G | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56977507; called by muse, mutect2, varscan2
- KLHL32 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV51521311; called by muse, mutect2, varscan2
- KLHL42 | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1289142544, COSV67145898; called by muse, mutect2, varscan2
- KLHL8 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56747914; called by muse, mutect2, varscan2
- KMT2E | c.4829dup p.L1610Ffs*259 | Frame Shift Ins (INS) | VAF 44/151 reads (29%) | catalogued as rs1243172283; called by mutect2, pindel, varscan2
- KRBA1 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs766194216, COSV55441638; called by muse, mutect2, varscan2
- KRT12 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV52430901; called by muse, varscan2
- KRTAP10-7 | c.450del p.C151Afs*29 | Frame Shift Del (DEL) | VAF 19/112 reads (17%) | catalogued as rs1555928560; called by mutect2, pindel, varscan2
- KRTAP15-1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375953985, COSV61877522; called by muse, mutect2, varscan2
- LAGE3 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.118); catalogued as COSV62074238; called by muse, mutect2, varscan2
- LAMB2 | c.4771C>T p.R1591W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs779316233, COSV59733733; called by mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 49/89 reads (55%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LBR | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs531565954, COSV55289043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCE2C | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.895); catalogued as rs777666120, COSV64228433; called by muse, mutect2, varscan2
- LCMT2 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV59790479; called by mutect2, varscan2
- LCN10 | c.436C>T p.H146Y (on ENST00000474369 / NM_001368089.1; = p.H159Y on NM_001001712.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs756202965, COSV57910383; called by muse, mutect2
- LDB3 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53941911; called by muse, mutect2, varscan2
- LGR5 | c.1550A>G p.Q517R | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV57005276; called by muse, mutect2, varscan2
- LIN7A | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54021708; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as rs780042765; called by mutect2, varscan2
- LIPT1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60739739; called by muse, mutect2, varscan2
- LLGL1 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.25); catalogued as COSV57498117; called by muse, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNA | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.511); catalogued as rs13768, CM020736, COSV61543017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPA | c.2731G>A p.V911I | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs932171816, COSV60298455, COSV60306182; called by muse, mutect2, varscan2
- LPCAT1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as rs1383309700, COSV52037749; called by muse, mutect2
- LPCAT4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs1566894633, COSV59216972; called by muse, mutect2, varscan2
- LPP | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as rs139718801; called by muse, mutect2, varscan2
- LRP1 | c.6122C>T p.T2041M | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs148823753; called by muse, mutect2, varscan2
- LRP5 | c.4150A>C p.S1384R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV53716094; called by muse, mutect2, varscan2
- LRRC4 | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV50814095; called by muse, mutect2, varscan2
- LRRC4B | c.1363G>C p.A455P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100975812; called by muse, mutect2, varscan2
- LRRC8A | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.487); catalogued as rs769346865, COSV52185936; called by muse, mutect2, varscan2
- LRRFIP2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs911369776, COSV60867840; called by muse, mutect2, varscan2
- LRRK1 | c.3196A>C p.T1066P | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.276); catalogued as COSV52612514; called by muse, mutect2, varscan2
- LRRTM1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV54439053; called by muse, mutect2, varscan2
- LTB4R2 | c.1154C>T p.P385L (on ENST00000528054; = p.P354L on NM_019839.5) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs371184608; called by muse, mutect2
- LTBP4 | c.4814G>A p.R1605H (on ENST00000308370 / NM_001042544.1; = p.R1568H on NM_003573.2) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.615); catalogued as rs777450656, COSV52577027; called by muse, mutect2
- LUC7L | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.163); catalogued as rs146490197, COSV53456700; called by muse, mutect2, varscan2
- LVRN | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV63497265; called by muse, mutect2
- LZTR1 | c.2368C>T p.R790W | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs767637944, COSV53147652; called by muse, mutect2, varscan2
- MAGED2 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.731); catalogued as COSV54497937; called by muse, mutect2, varscan2
- MAGEE1 | c.2414T>G p.L805R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63908813, COSV63909025; called by muse, mutect2, varscan2
- MAGOHB | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs1050010220, COSV57898503; called by muse, mutect2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP2K7 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607673; called by muse, mutect2, varscan2
- MAP2K7 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1441304667, COSV67608310, COSV67609148; called by muse, mutect2, varscan2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 49/167 reads (29%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAPRE1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 59/427 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV65032886; called by muse, mutect2, varscan2
- MARVELD3 | c.948dup p.Y317Vfs*22 | Frame Shift Ins (INS) | VAF 13/45 reads (29%) | catalogued as rs747980715; called by mutect2, varscan2
- MAST1 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766694390, COSV52243329; called by muse, mutect2, varscan2
- MATN1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs147880584; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 50/146 reads (34%) | catalogued as rs749738168; called by mutect2, pindel, varscan2
- MBOAT2 | c.507-1G>T p.X169_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV60009187; called by muse, mutect2, varscan2
- MBOAT7 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs748238566, COSV55475881, COSV99824729; called by muse, mutect2, varscan2
- MBTPS1 | c.3083C>T p.P1028L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1372724887, COSV58570867; called by muse, mutect2, varscan2
- MBTPS1 | c.2251G>A p.G751R | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748969675, COSV58570870; called by muse, mutect2, varscan2
- MCCC1 | c.1728G>A p.M576I | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV55608797; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 42/94 reads (45%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM4 | c.2341G>A p.V781M | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs765226208, COSV50623703; called by muse, mutect2, varscan2
- MDN1 | c.10307C>T p.A3436V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1273453343, COSV65522055; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MED12L | c.418del p.E140Rfs*7 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | catalogued as COSV56395375; called by mutect2, pindel, varscan2
- METTL24 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58822205; called by muse, mutect2
- MFHAS1 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); catalogued as COSV52282462; called by muse, mutect2, varscan2
- MFSD14B | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64700917; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs762448666; called by mutect2, varscan2
- MIER1 | c.1305A>C p.K435N (on ENST00000355356 / NM_001077701.3; = p.K452N on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV62530429; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs749903408; called by mutect2, varscan2
- MMGT1 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs150859420, COSV60003368; called by muse, mutect2, varscan2
- MMP9 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs373663809; called by muse, mutect2, varscan2
- MMS22L | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV51521331; called by muse, mutect2, varscan2
- MNX1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM067698, COSV99429520; called by muse, mutect2
- MOB3A | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs746262774, COSV63865704; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | catalogued as rs755830405; called by mutect2, varscan2
- MPHOSPH8 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1473185738, COSV64055683; called by muse, mutect2, varscan2
- MPP2 | c.664del p.R222Afs*33 (on ENST00000461854 / NM_001278372.2; = p.R198Afs*33 on NM_005374.5) | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as COSV52238866; called by mutect2, pindel, varscan2
- MPP2 | c.526G>T p.G176C (on ENST00000461854 / NM_001278372.2; = p.G152C on NM_005374.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52236000; called by muse, mutect2, varscan2
- MPP2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV52236019; called by muse, mutect2, varscan2
- MROH1 | c.4234G>A p.G1412R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1304337842; called by muse, mutect2, varscan2
- MROH2B | c.3380C>T p.T1127I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV68184545; called by muse, mutect2, varscan2
- MS4A15 | c.632A>C p.N211T (on ENST00000405633 / NM_001098835.2; = p.N118T on NM_152717.3) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100558810; called by mutect2, varscan2
- MTERF1 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as rs551906573, COSV61098294; called by muse, mutect2, varscan2
- MTF1 | c.1232C>T p.T411I | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV65989233; called by muse, mutect2, varscan2
- MTF1 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65989239; called by muse, mutect2, varscan2
- MTMR4 | c.15del p.S8Afs*16 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as COSV100051534; called by mutect2, pindel, varscan2
- MTMR9 | c.353A>G p.E118G | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV55312581; called by muse, mutect2, varscan2
- MTOR | c.7595C>T p.A2532V | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63871886; called by muse, mutect2, varscan2
- MUC16 | c.17747A>G p.Q5916R | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV67468284; called by muse, mutect2, varscan2
- MUC6 | c.5254C>T p.H1752Y | Missense Mutation (SNP) | VAF 104/1036 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); catalogued as rs748398292, COSV101424364; called by muse, varscan2
- MXRA5 | c.3085C>A p.P1029T | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.559); catalogued as COSV54236030; called by muse, mutect2, varscan2
- MYBBP1A | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs765199525, COSV54597876; called by muse, mutect2, varscan2
- MYEOV | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs758378495, COSV58294322; called by muse, mutect2, varscan2
- MYH10 | c.4669G>A p.A1557T | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.845); catalogued as COSV52601643; called by muse, mutect2, varscan2
- MYH7 | c.4145G>A p.R1382Q | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs727504325, CM133942, COSV100805760, COSV62517935; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- MYH8 | c.3598G>A p.A1200T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV67965573; called by muse, mutect2, varscan2
- MYLK | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.131); catalogued as rs531232445, COSV60610738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1G | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs144045009; called by muse, mutect2, varscan2
- MYO5C | c.3794A>G p.E1265G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV55903671, COSV99953939; called by muse, mutect2, varscan2
- MYOF | c.6089G>A p.G2030D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as rs761081912, COSV63704559; called by muse, mutect2, varscan2
- MYORG | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773512111, COSV99898276; called by muse, varscan2
- MYPN | c.628_630del p.S210del | In Frame Del (DEL) | VAF 18/66 reads (27%) | catalogued as rs749944961; called by pindel, varscan2
- MZT2B | c.440del p.G147Afs*? | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs772879277; called by mutect2, pindel, varscan2
- NAAA | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs777433295, COSV54432217; called by muse, mutect2, varscan2
- NAALADL1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); catalogued as rs369091785; called by muse, mutect2, varscan2
- NABP2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs759250167, COSV57191821; called by muse, mutect2, varscan2
- NAE1 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV51976464; called by muse, mutect2, varscan2
- NAGLU | c.1787G>A p.G596D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1243561393, COSV56794847; called by muse, mutect2
- NALCN | c.5011C>T p.R1671C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs143587652; called by muse, mutect2, varscan2
- NAP1L1 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs746496742, COSV53874616; called by muse, mutect2, varscan2
- NAP1L3 | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV59075654; called by muse, mutect2, varscan2
- NAPG | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs916066691, COSV59796723; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs763376147; called by mutect2, varscan2
- NBPF1 | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as COSV55326700; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | catalogued as rs770284236; called by mutect2, pindel
- NCKAP1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs142669044; called by muse, mutect2, varscan2
- NCOR2 | c.1586C>A p.A529E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as rs376669119, COSV62304820; called by muse, mutect2, varscan2
- NEB | c.5161G>A p.E1721K | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs750732565, COSV51419215, COSV51443067; called by muse, mutect2, varscan2
- NEFM | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55332325; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 80/183 reads (44%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEXMIF | c.3190C>T p.R1064C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195044913, COSV50032739; called by muse, mutect2, varscan2
- NF1 | c.2990G>T p.R997M | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1555614462, CM143354, CS1311519, COSV62202923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC2IP | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs372049949; called by mutect2, varscan2
- NFE2L1 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs144484468; called by muse, mutect2, varscan2
- NFKBID | c.467C>T p.P156L (on ENST00000396901; = p.P308L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs1440823199, COSV61727733; called by muse, mutect2, varscan2
- NID1 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs752565337, COSV51617958; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NIM1K | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58141819; called by muse, mutect2, varscan2
- NLGN3 | c.2354G>A p.R785H (on ENST00000358741 / NM_181303.2; = p.R765H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.176); catalogued as rs754598273, COSV62443346; called by muse, mutect2, varscan2
- NLRC5 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs780658848, COSV52650308; called by muse, mutect2, varscan2
- NLRC5 | c.1667G>A p.G556D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV52655503; called by muse, mutect2, varscan2
- NMNAT1 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs201994921, CM155281, COSV65882648; called by muse, mutect2, varscan2
- NOP14 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.266); catalogued as COSV58625163; called by muse, mutect2, varscan2
- NOS1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763590379, COSV57613190; called by muse, mutect2, varscan2
- NPEPL1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.55); catalogued as rs751719832, COSV61939129; called by muse, mutect2, varscan2
- NRF1 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs754280971, COSV56212442; called by muse, mutect2, varscan2
- NRIP3 | c.317A>G p.D106G | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV58469877; called by muse, mutect2, varscan2
- NRK | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54597186; called by muse, mutect2, varscan2
- NRK | c.2344del p.I782Lfs*66 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV54591328; called by mutect2, varscan2
- NRXN1 | c.3710A>G p.Y1237C | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60499950; called by muse, mutect2, varscan2
- NSG2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.38); catalogued as rs142224266; called by muse, mutect2, varscan2
- NSMF | c.1153G>A p.E385K (on ENST00000371475 / NM_001130969.3; = p.E383K on NM_015537.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1266516122, COSV55811511; called by muse, mutect2, varscan2
- NTSR1 | c.1143C>G p.C381W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.318); catalogued as COSV65138696; called by muse, mutect2, varscan2
- NUBP2 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.337); catalogued as rs769308285, COSV51905919; called by muse, mutect2, varscan2
- NUP205 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs777937995, COSV53659512; called by muse, mutect2, varscan2
- NUP205 | c.3612dup p.D1205* | Frame Shift Ins (INS) | VAF 28/96 reads (29%) | catalogued as rs1179933291; called by mutect2, varscan2
- NUP98 | c.5374A>G p.M1792V (on ENST00000359171 / NM_001365126.1; = p.M1775V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1437926628, COSV51709483; called by muse, mutect2, varscan2
- NUTM1 | c.1033dup p.R345Pfs*6 | Frame Shift Ins (INS) | VAF 8/48 reads (17%) | catalogued as rs756300195; called by mutect2, pindel
- NUTM1 | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as rs200540515; called by muse, mutect2, varscan2
- NWD1 | c.3923G>A p.S1308N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.866); catalogued as COSV60342973; called by muse, mutect2, varscan2
- NYAP2 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as rs761588621, COSV56005652, COSV56016052, COSV99796255; called by muse, mutect2, varscan2
- NYNRIN | c.2456T>C p.M819T | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.756); catalogued as rs772745095, COSV66842646; called by muse, mutect2, varscan2
- NYNRIN | c.3481C>T p.R1161C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777661158, COSV66840935; called by muse, mutect2, varscan2
- OASL | c.1258T>G p.S420A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.137); catalogued as COSV56567299; called by muse, mutect2, varscan2
- ONECUT2 | c.1057del p.Q353Rfs*123 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as COSV101529825; called by mutect2, pindel, varscan2
- OPHN1 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV62782542; called by muse, mutect2, varscan2
- OR10G4 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.352); catalogued as COSV57977699; called by muse, mutect2, varscan2
- OR10G7 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 68/246 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV57867205, COSV57869169; called by muse, mutect2, varscan2
- OR13G1 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs200763482, COSV100687494, COSV62943805; called by muse, mutect2, varscan2
- OR2T33 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100531506; called by muse, mutect2, varscan2
- OR4B1 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as COSV58882938; called by muse, mutect2, varscan2
- OR4X1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.894); catalogued as rs61915300; called by muse, mutect2, varscan2
- OR51F1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1446650213, COSV58579826; called by muse, mutect2, varscan2
- OR51V1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs761721053, COSV58315209; called by muse, mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 76/108 reads (70%) | catalogued as rs746200712; called by mutect2, varscan2
- ORC6 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1261990366, COSV54624199; called by muse, mutect2, varscan2
- OSGEP | c.652A>G p.M218V | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV52832356; called by muse, mutect2, varscan2
- OTOR | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV55722202; called by muse, varscan2
- OTOR | c.186dup p.G63Rfs*27 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs747190613; called by pindel, varscan2
- OTULINL | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV57034114; called by muse, mutect2, varscan2
- OXR1 | c.266G>A p.R89Q (on ENST00000442977 / NM_001198532.1; = p.R88Q on NM_018002.3) | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs541833758, COSV56325280; called by muse, mutect2, varscan2
- P4HA2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as rs148040234; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs763394045; called by mutect2, varscan2
- PA2G4 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV57568732; called by muse, mutect2, varscan2
- PACS1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.413); catalogued as rs780310274, COSV57697781; called by muse, mutect2, varscan2
- PADI2 | c.93C>T p.S31= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as rs764574108, COSV64945888, COSV64945910; called by muse, mutect2, varscan2
- PALLD | c.2011G>T p.E671* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | catalogued as COSV54981161; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.392C>T p.T131M (on ENST00000374531 / NM_001037293.2; = p.T129M on NM_007203.5) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.139); catalogued as rs150674445; called by muse, mutect2, varscan2
- PAMR1 | c.1382G>A p.R461H (on ENST00000619888 / NM_001001991.3; = p.R478H on NM_015430.4) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as rs372889720; called by muse, mutect2, varscan2
- PAN2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV57754007; called by muse, mutect2, varscan2
- PAQR9 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757779427, COSV61418252; called by muse, mutect2, varscan2
- PARN | c.1821G>T p.K607N | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV58366489; called by muse, mutect2, varscan2
- PAX1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV68271968; called by muse, mutect2, varscan2
- PBRM1 | c.4135C>T p.R1379W (on ENST00000296302 / NM_001366071.2; = p.R1327W on NM_018313.5) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56277669; called by muse, mutect2
- PCARE | c.2099G>T p.G700V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV59055093, COSV59058333; called by muse, mutect2, varscan2
- PCDH15 | c.2309G>A p.S770N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV100216215, COSV57315328; called by muse, mutect2, varscan2
- PCDHA1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs149577981, COSV65374522; called by muse, mutect2, varscan2
- PCDHA1 | c.1856G>A p.R619H | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.12); catalogued as COSV65373699; called by muse, mutect2
- PCDHA3 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs782417260, COSV63541935; called by muse, mutect2, varscan2
- PCDHA5 | c.1405C>A p.P469T | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65352629; called by muse, mutect2, varscan2
- PCDHA6 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.043); catalogued as rs782089682, COSV65344334; called by muse, mutect2, varscan2
- PCDHB16 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV53362684; called by muse, mutect2, varscan2
- PCDHB7 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1554280024, COSV50770160; called by muse, mutect2, varscan2
- PCDHB7 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs782586618, COSV50769229; called by muse, mutect2, varscan2
- PCDHB9 | c.1176del p.L393* | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as rs782200278; called by mutect2, pindel, varscan2
- PCDHB9 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53379089; called by muse, mutect2, varscan2
- PCDHGA2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as rs770199497, COSV53894862; called by muse, mutect2, varscan2
- PCDHGA6 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.668); catalogued as rs749769645; called by muse, mutect2, varscan2
- PCLO | c.15176C>A p.S5059Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV61624238; called by muse, mutect2, varscan2
- PCNX1 | c.5132C>T p.S1711L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53095111; called by muse, mutect2, varscan2
- PCSK5 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239815202, COSV100949395, COSV65089207; called by muse, mutect2, varscan2
- PDCD6IP | c.887A>T p.N296I | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.219); catalogued as rs1369262116, COSV56243334; called by muse, mutect2, varscan2
- PDCL3 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51809299; called by muse, mutect2, varscan2
- PDE3A | c.2939C>A p.A980D | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62973526; called by muse, mutect2, varscan2
- PDE6A | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs142092713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE7A | c.897C>A p.F299L (on ENST00000401827 / NM_001242318.3; = p.F273L on NM_002603.4) | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as COSV65153186; called by muse, mutect2, varscan2
- PDGFB | c.657del p.K220Rfs*16 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs1274478632; called by mutect2, pindel, varscan2
- PDHA2 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54779357; called by muse, mutect2, varscan2
- PDILT | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.195); catalogued as rs201187995; called by muse, mutect2, varscan2
- PDLIM4 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV53804194; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs747131399; called by mutect2, varscan2
- PDS5B | c.4177G>A p.V1393I | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59727396; called by muse, mutect2, varscan2
- PDZRN3 | c.2975G>A p.R992H | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55200778; called by muse, mutect2, varscan2
- PEAR1 | c.2810G>C p.G937A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs780348327, COSV52773250; called by muse, mutect2, varscan2
- PEG3 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV55634565; called by muse, mutect2, varscan2
- PELO | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs984090337, COSV50882847; called by muse, mutect2, varscan2
- PFKP | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.941); catalogued as rs753541438, COSV66897369; called by muse, mutect2, varscan2
- PGAP2 | c.584_586del p.F195del (on ENST00000463452 / NM_001346398.2; = p.F256del on NM_014489.4) | In Frame Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs777098385; called by pindel, varscan2
- PGBD1 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1172498085, COSV52551902; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 60/84 reads (71%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF10 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV59322174; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF2 | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs745947229, COSV63680602; called by muse, mutect2, varscan2
- PHRF1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs549849218, COSV52756155; called by muse, mutect2, varscan2
- PIGB | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179198642, COSV51241309; called by muse, mutect2
- PIK3CG | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63248752; called by muse, mutect2, varscan2
- PIP4K2A | c.941del p.P314Qfs*8 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | catalogued as rs755454854; called by mutect2, pindel, varscan2
- PIP5K1C | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.023); catalogued as rs781188139, COSV58952279; called by muse, mutect2, varscan2
- PKHD1L1 | c.7581del p.F2527Lfs*2 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as rs1367468478; called by mutect2, pindel, varscan2
- PKP1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146785756; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCB1 | c.3619A>G p.I1207V | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as rs754119167, COSV100569132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCL1 | c.2323A>G p.N775D | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as COSV70834388; called by muse, mutect2, varscan2
- PLCL1 | c.3203C>A p.P1068H | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV70834544; called by muse, mutect2, varscan2
- PLCL2 | c.706G>A p.A236T (on ENST00000615277 / NM_001144382.2; = p.A110T on NM_015184.5) | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs369130951, COSV67620618; called by muse, mutect2, varscan2
- PLEKHA4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1405844450, COSV54362796; called by muse, mutect2, varscan2
- PLEKHA4 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs760684162, COSV54363258; called by muse, mutect2, varscan2
- PLIN4 | c.1591G>A p.V531M (on ENST00000301286; = p.V546M on NM_001367868.2) | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.164); catalogued as rs755459936, COSV56691600; called by muse, mutect2, varscan2
- PLXNB2 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs372428698; called by muse, mutect2, varscan2
- PLXNB3 | c.5038C>T p.R1680C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199536649, COSV100737041; called by muse, varscan2
- PMPCA | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65509436; called by muse, mutect2, varscan2
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs761459630; called by mutect2, pindel
- PNPLA7 | c.1712T>C p.L571P | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52999302; called by muse, mutect2, varscan2
- POLG2 | c.457_458del p.L153Tfs*11 | Frame Shift Del (DEL) | VAF 41/143 reads (29%) | catalogued as rs1568093387; called by pindel, varscan2
- POLQ | c.1470C>T p.G490= | Splice Region (SNP) | VAF 24/71 reads (34%) | catalogued as rs778193670, COSV51752435; called by muse, mutect2, varscan2
- POLR3C | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs782511256, COSV61936155, COSV61936625; called by muse, mutect2, varscan2
- POM121C | c.1129G>A p.A377T (on ENST00000607367; = p.A135T on NM_001099415.3) | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs184994746, COSV57545780; called by muse, mutect2, varscan2
- POU3F4 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894924, CM005401, COSV100937204, COSV64539129; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPL | c.2967del p.Q990Rfs*31 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | catalogued as rs762995701; called by mutect2, pindel, varscan2
- PRAG1 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV58161310; called by muse, mutect2, varscan2
- PRDM8 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60203672; called by muse, mutect2, varscan2
- PRDX3 | c.68dup p.I24Hfs*50 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | catalogued as rs773309337; called by mutect2, pindel, varscan2
- PREX2 | c.1598T>A p.M533K | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV55771666; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | catalogued as rs764112302; called by mutect2, varscan2
- PREX2 | c.3773A>G p.E1258G | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as COSV55771679; called by muse, varscan2
- PREX2 | c.3818C>T p.A1273V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs775225179, COSV55771686, COSV99905130; called by muse, varscan2
- PRICKLE1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762434475, COSV61543440; called by muse, mutect2, varscan2
- PRPF40B | c.58G>T p.G20W (on ENST00000380281; = p.G14W on NM_012272.3) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99979249; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 48/68 reads (71%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRC2A | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63224584; called by muse, mutect2, varscan2
- PRRC2A | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs747752054, COSV65686653; called by mutect2, varscan2
- PRRC2B | c.6563_6565del p.Q2188del | In Frame Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs776953432; called by pindel, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 50/113 reads (44%) | catalogued as rs781858060; called by mutect2, varscan2
- PRRG3 | c.494dup p.R166Qfs*14 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as rs748526759; called by mutect2, varscan2
- PSMC3IP | c.634G>A p.V212I (on ENST00000393795 / NM_016556.4; = p.V200I on NM_013290.6) | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as rs149230650; called by muse, mutect2, varscan2
- PSMC4 | c.598dup p.R200Pfs*43 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | catalogued as rs765768285; called by mutect2, varscan2
- PSMC4 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50095286; called by muse, mutect2, varscan2
- PSMD8 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs367675318; called by muse, mutect2, varscan2
- PTCHD4 | c.2389C>A p.L797M | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV59785201; called by muse, mutect2, varscan2
- PTCRA | c.164del p.P55Lfs*113 | Frame Shift Del (DEL) | VAF 23/92 reads (25%) | catalogued as COSV58975439; called by mutect2, pindel, varscan2
- PTGFR | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100882221; called by muse, mutect2, varscan2
- PTGS2 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV66569477; called by muse, mutect2, varscan2
- PTK2 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 34/157 reads (22%) | catalogued as COSV61786171; called by muse, mutect2, varscan2
- PTPRF | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as rs372831256; called by muse, mutect2, varscan2
- PTPRK | c.2742C>A p.N914K (on ENST00000368215 / NM_001291984.2; = p.N915K on NM_002844.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1477472561, COSV63896461; called by muse, mutect2, varscan2
- PUM1 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57085690; called by muse, mutect2, varscan2
- PXDN | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs752428115, COSV99412005, COSV99414014; called by muse, varscan2
- PXDNL | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62487762, COSV62501020; called by muse, varscan2
- PXN | c.1441C>T p.R481W (on ENST00000228307 / NM_001080855.3; = p.R447W on NM_002859.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768579833, COSV57218924; called by muse, mutect2, varscan2
- PZP | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs758095537, COSV54361303; called by muse, mutect2, varscan2
- RAB39B | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 147/441 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs782363257, COSV65624661; called by muse, mutect2, varscan2
- RAB3GAP2 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV52965853; called by muse, mutect2, varscan2
- RABEPK | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs144370574, COSV52335508; called by muse, mutect2, varscan2
- RAD21 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV52059266; called by muse, mutect2, varscan2
- RADX | c.644-1G>C p.X215_splice | Splice Site (SNP) | VAF 19/67 reads (28%) | catalogued as COSV65318710; called by muse, mutect2, varscan2
- RANGAP1 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62363509; called by muse, mutect2, varscan2
- RAPGEF5 | c.647del p.K216Rfs*22 (on ENST00000401957 / NM_001367602.2; = p.K519Rfs*22 on NM_012294.5) | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs770990761; called by mutect2, pindel, varscan2
- RARRES1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs777701079, COSV52962479; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
877 further variants in this file (496 protein-altering or splice-affecting, 343 silent, 38 other) are not listed here.
